Gene-level copy-number profile of tumor specimen TCGA-DD-A4ND-01A from TCGA case TCGA-DD-A4ND, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 56.9 years (20,782 days).
Specimen TCGA-DD-A4ND-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.7c722599-e7a2-47d0-8cdd-049c32b7b2c1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-A4ND-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cde2e7bf-b081-4e7a-ab3b-625cf59bec27

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 8,294; copy number 3: 44; copy number 4: 33,403; copy number 5: 11; copy number 6: 16,206; copy number 7: 1,507; copy number 8: 17; copy number 11: 8; copy number 13: 144; copy number 15: 3; copy number 25: 12; copy number 28: 11; copy number 31: 76; copy number 38: 22; copy number 50: 61.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-A4ND-01A-11D-A25U-01): tumor purity 0.4, ploidy 2.16, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 337 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:38,844,866–39,730,065, 14 genes, copy number 13–28 (within-gene range 6–28): AC067817.2, PLEKHA2, AC108863.1, HTRA4, TM2D2, ADAM9, SNORD38D, ADAM32, RPL3P10, AC105185.1, ADAM5, ADAM3A, AC123767.1, ADAM18.
- chr8:40,530,590–41,032,998, 3 genes, copy number 15 (within-gene range 6–15): ZMAT4, AC048387.1, RNU6-356P.
- chr11:54,591,480–56,790,965, 128 genes, copy number 13 (broad region; genes not listed).
- chr11:61,615,036–62,169,828, 24 genes, copy number 13–25 (within-gene range 2–25): RPLP0P2, AP002754.2, DAGLA, MYRF-AS1, MYRF, TMEM258, MIR611, FEN1, FADS2, FADS1, MIR1908, FADS3, MIR6746, RAB3IL1, RNU6-1243P, BEST1, FTH1, AP003733.3, AP003733.1, LINC02733, AP003733.2, AP002793.1, INCENP, EEF1DP8.
- chr11:66,614,964–71,423,423, 160 genes, copy number 25–50 (within-gene range 5–50) (broad region; genes not listed).
- chr12:28,133,249–28,581,511, 8 genes, copy number 11: CCDC91, AC022364.1, AC022364.2, AC022079.2, AC022079.1, RNU4-54P, RNA5SP355, AC084754.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
